CMI case MBCproject_0253 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/a6b660fc-8b27-4480-ace7-fd4d00eec83b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (4 samples)
- Sample MBCproject_0253_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCproject_0253_T1_RNA, MBCproject_0253_T1_WES (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
- Sample MBCproject_0253_T2_RNA: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Thyroid; Preservation method: FFPE.
